Gene-level copy-number profile of tumor specimen ALCH-AE0N-TTP1-A from ALCHEMIST case ALCH-AE0N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.0 years (29,235 days).
Specimen ALCH-AE0N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f7863ed3-20ea-43c7-9dc9-272b03cfdc47.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE0N-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/c600a72b-c67e-459b-bd5b-2bd0d7d20326

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 626; copy number 1: 15,412; copy number 2: 38,845; copy number 3: 3,987; copy number 4: 18; copy number 7: 1; copy number 11: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:12,877,522–12,885,211, 1 gene: LINC02022.
- chr3:46,668,995–46,693,704, 1 gene: ALS2CL.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:68,573,782–68,589,512, 1 gene (within-gene range 0–1): AC126773.3.
- chr17:2,689,386–3,037,741, 9 genes (within-gene range 0–1): CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr17:16,414,524–16,492,193, 9 genes: AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr19:7,476,875–7,534,009, 6 genes (within-gene range 0–1): PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1.
- chr19:18,868,545–18,919,387, 4 genes (within-gene range 0–1): GDF1, CERS1, AC005197.1, COPE.
- chr20:33,031,648–33,048,152, 2 genes: BPIFB6, PUDPP3.
- chr22:19,146,993–19,150,292, 1 gene: GSC2.
- chr22:45,875,932–45,879,247, 1 gene (within-gene range 0–1): BX324167.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,623,557–248,645,278, 2 genes, copy number 11: OR2T11, OR2T35.
- chr7:74,796,144–74,851,551, 1 gene, copy number 7: GTF2IRD2.
- chr16:28,413,703–28,415,018, 1 gene, copy number 13: CDC37P2.

Autosomal genes at a single copy (total copy number 1): 13,152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
